Surgical pathology report (de-identified scan), TCGA case TCGA-D8-A1XW, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D8-A1XW-01A (Primary Tumor).

Department of Cancer Pathology

copy No.

Date:

Examination: Histopathological examination

Internal invoice No.

Value of diagnostic procedure

Examination No.

Patient: XXX

PESEL: XXX

Age:

Gender: F

Material: **Multiple organ resection – left breast†**

Unit in charge:

Physician in charge:

Material collected on:

Material received on:

Expected time of examination: **up to 8 working days**Clinical diagnosis: **Cancer of the left breast.**PCI: **Carcinoma invasivum G3.**

ICD-0-3

Carcinoma, infiltrating duct, nos 8500/3
Site: breast, NOS C50.9 for 4/12/11

Examination performed on:

Results of immunohistochemical examination:

No estrogen receptors detected in neoplastic cell nuclei. Progesterone receptors found in less than 10% of neoplastic cell nuclei. HER2 protein stained with Ventana's Pathway HER-2/neu (4B5) Rabbit Monoclonal Antibody. Negative reaction in invasive cancerous cells (Score=1+).

Compliance validate

Examination performed on

Macroscopic description:

Left breast, sized 26 x 18 x 5 cm, removed along with axillary tissues sized 4 x 1 x 2 cm and a skin flap of 16 x 11 cm. Weight 220 g. Tumour sized 3.5 x 2.5 x 3.0 cm found in the upper inner quadrant, located 4 cm from the upper edge, 0.5 cm from the base and 3.8 cm from the skin.

Microscopic description:

Carcinoma ductale invasivum - NHG3 (3+3+2: 9 mitoses/10 HPF - visual area: 0.55mm).

Mamilla sine laesionibus.

Glandular tissue showing lesions: mastopathia fibrosa.

Axillary lymph nodes:

Lymphonodulitis chronica (No I).

Histopathological diagnosis:

Carcinoma ductale invasivum mammae sinistae: **Invasive ductal carcinoma of the left breast.**
(NHG3, p 12, pNO).

Compliance validated by:

CONTACT YOUR DOCTOR WITH THIS REPORT!

Reviewed initials	Date Reviewed: 4/12/11	

Source: NCI Genomic Data Commons file ff651cc6-db63-4637-b0e4-84ada73ccd1f (TCGA-D8-A1XW.BD71F606-58BC-46B9-8A03-CB25D5BECA96.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).